Somatic mutation profile of tumor specimen TCGA-B0-4842-01A (aliquot TCGA-B0-4842-01A-02D-1421-08) from TCGA case TCGA-B0-4842, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 74.0 years (27,019 days).
Specimen TCGA-B0-4842-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27782a03-3f65-4073-a7cf-242225a6eac2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4842-11A (Solid Tissue Normal), aliquot TCGA-B0-4842-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d475f2d-60bc-4077-953d-a82a4cbf4bea

The open-access MAF lists 54 somatic variants for this specimen: 48 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 37, Silent 6, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.464-1G>A p.X155_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | hotspot (GDC flag); catalogued as rs5030817, CS071276, CS941547, CS961706, COSV56542304, COSV56544494, COSV56544554, COSV56553901; ClinVar: pathogenic; called by mutect2, varscan2
- ANKRD50 | c.3434A>C p.D1145A | Missense Mutation (SNP) | VAF 66/388 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.051); catalogued as COSV72386169; called by muse, mutect2, varscan2
- ARHGAP30 | c.2449G>A p.G817S | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV63518731; called by muse, mutect2, varscan2
- ASGR2 | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs767191672, COSV54689161, COSV54691237; called by muse, mutect2, varscan2
- ATP13A5 | c.2869C>A p.P957T | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV60873788; called by muse, mutect2, varscan2
- CACNA1I | c.5513G>A p.C1838Y | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.362); catalogued as COSV60816173; called by muse, mutect2, varscan2
- CSNK1G2 | c.1229C>A p.S410* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as rs949171867, COSV55339172, COSV55339992; called by muse, mutect2, varscan2
- DHX36 | c.1388A>T p.E463V | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV57676360; called by muse, mutect2, varscan2
- DISP1 | c.3829T>C p.Y1277H | Missense Mutation (SNP) | VAF 63/359 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as COSV52663807; called by muse, mutect2, varscan2
- DMPK | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781085771, COSV52181477, COSV99353364; called by muse, mutect2, varscan2
- DNAH10 | c.8742C>G p.N2914K (on ENST00000409039; = p.N2853K on NM_207437.3) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.222); catalogued as COSV68999608; called by muse, mutect2
- EBNA1BP2 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV52541207; called by muse, mutect2, varscan2
- FLG2 | c.5627G>T p.R1876M | Missense Mutation (SNP) | VAF 74/458 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV101166318, COSV66171947; called by muse, mutect2, varscan2
- HLA-E | c.8A>G p.D3G | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs937558103, COSV64927851; called by muse, mutect2, varscan2
- IGSF10 | c.2657C>T p.T886I | Missense Mutation (SNP) | VAF 165/900 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56782480, COSV56790486; called by muse, mutect2, varscan2
- IRAK1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV57656225; called by muse, mutect2
- LARP4 | c.127T>A p.W43R | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53326283; called by muse, mutect2, varscan2
- LETMD1 | c.842C>G p.T281S | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.119); catalogued as COSV50399420; called by muse, mutect2, varscan2
- MAP3K11 | c.2476dup p.Q826Pfs*36 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | catalogued as rs1250719675; called by mutect2, pindel
- MCF2 | c.224A>T p.Q75L | Missense Mutation (SNP) | VAF 56/317 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58492775; called by muse, mutect2, varscan2
- MEFV | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs377250147; called by muse, mutect2, varscan2
- MFSD1 | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 69/444 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51842695; called by muse, mutect2, varscan2
- MVP | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62423182; called by muse, mutect2
- NCOR1 | c.5798T>C p.I1933T | Missense Mutation (SNP) | VAF 75/544 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762513108, COSV51990972; called by muse, mutect2, varscan2
- NOP14 | c.647A>G p.E216G | Missense Mutation (SNP) | VAF 91/594 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV58627291; called by muse, mutect2, varscan2
- NRBP1 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV51995516; called by muse, mutect2, varscan2
- NRXN1 | c.2498G>C p.G833A | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV58483691; called by muse, mutect2
- OR51F1 | c.286T>A p.F96I | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV58580610; called by muse, mutect2, varscan2
- ORC4 | c.1133A>G p.H378R | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.896); catalogued as COSV51576437; called by muse, mutect2, varscan2
- PBRM1 | c.3154C>T p.R1052* (on ENST00000296302 / NM_001366071.2; = p.R1027* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 11/122 reads (9%) | catalogued as COSV56260610; called by muse, mutect2
- PCDHA13 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1313975286, COSV56487940; called by muse, mutect2, varscan2
- PDP2 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61241403; called by muse, mutect2, varscan2
- PYCR2 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs756981499, COSV59525411; called by muse, mutect2, varscan2
- RBM27 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); catalogued as COSV54593241; called by muse, mutect2
- RBM27 | c.727A>T p.I243F | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV54593249; called by muse, mutect2
- RTTN | c.3779T>C p.L1260P | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55350442; called by muse, mutect2, varscan2
- SPTBN1 | c.6019G>T p.E2007* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV61692698; called by muse, mutect2, varscan2
- SV2C | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs759085527, COSV59227182; called by muse, mutect2, varscan2
- TAF1 | c.3086G>A p.R1029H (on ENST00000373790 / NM_138923.4; = p.R1050H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52117959; called by muse, mutect2, varscan2
- TERT | c.3112G>A p.D1038N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV57218527, COSV57233910; called by muse, mutect2
- ZNF75D | c.125A>C p.N42T | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs782539455, COSV66133331; called by muse, mutect2, varscan2
- ZNF91 | c.2399G>A p.C800Y | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56091191; called by muse, mutect2, varscan2
- ANK2 | c.10939del p.H3647Ifs*128 | Frame Shift Del (DEL) | VAF 37/297 reads (12%) | called by mutect2, pindel, varscan2
- CCAR1 | c.826+1G>T p.X276_splice | Splice Site (SNP) | VAF 26/246 reads (11%) | called by mutect2, varscan2
- FCGBP | c.5693C>T p.P1898L | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LIFR | c.2395del p.A799Lfs*30 | Frame Shift Del (DEL) | VAF 18/133 reads (14%) | called by mutect2, pindel, varscan2
- NIP7 | c.149_151del p.K50del | In Frame Del (DEL) | VAF 10/89 reads (11%) | called by pindel, varscan2
- TSC1 | c.1328del p.G443Dfs*14 | Frame Shift Del (DEL) | VAF 23/133 reads (17%) | called by mutect2, pindel, varscan2
- BAP1 | c.936T>G p.G312= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV56239275; called by muse, mutect2, varscan2
- CNTN2 | c.2817A>C p.R939= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV59352281; called by muse, mutect2, varscan2
- HEXD | c.675C>T p.Y225= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV60065549; called by muse, mutect2, varscan2
- KLHL1 | c.390G>T p.V130= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as COSV64780432; called by muse, mutect2, varscan2
- MROH2B | c.399C>A p.L133= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV68188336; called by muse, mutect2, varscan2
- NELL1 | c.1509C>T p.T503= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs780331135, COSV54312603; called by muse, mutect2, varscan2
